Somatic mutation profile of tumor specimen TARGET-40-NAAHBU-01A (aliquot TARGET-40-NAAHBU-01A-01D) from TARGET case TARGET-40-NAAHBU, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.9 years (4,342 days).
Specimen TARGET-40-NAAHBU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbbcb85d-dde7-4493-9156-5df8c05b5454.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHBU-10A (Blood Derived Normal), aliquot TARGET-40-NAAHBU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf9e9e5d-1d4f-4b56-8721-f0beae2e872f

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 47/78 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TACC2 | c.6056C>T p.S2019F (on ENST00000334433; = p.S97F on NM_006997.4) | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166796802; called by muse, mutect2, varscan2
- GULP1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PKHD1 | c.8863C>A p.R2955= | Silent (SNP) | VAF 136/404 reads (34%) | catalogued as rs1229564017; called by muse, mutect2, varscan2
- TACC2 | c.7200C>T p.I2400= (on ENST00000334433; = p.I478= on NM_006997.4) | Silent (SNP) | VAF 41/237 reads (17%) | catalogued as COSV53281653; called by muse, mutect2, varscan2
- TERT | c.1854G>A p.T618= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as rs746040728, COSV57239665; ClinVar: likely benign; called by muse, mutect2, varscan2
- THSD7A | c.186G>A p.K62= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
